CCDI case PBBXMW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/0bf7ddb9-bd49-4f86-b79f-837baeda4d70

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 2.5 years (927 days).

Biospecimens (3 samples)
- Sample 0DK83T: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DK83Z: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DK84F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
